TCGA case TCGA-06-0238 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eddbca7a-d668-4c5d-9843-340d7f18e30e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 405 days (1.1 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 46.6 years (17,037 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 47.5 years (17,348 days); Days to diagnosis: 311 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 311 (post initial treatment): Progression or recurrence: Yes; Days to progression: 311 days.
- Days to follow up: 359 days; Disease response: With Tumor.
- Days to follow up: 405 days (1.1 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0238-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-06-0238-01A-01-BS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-06-0238-01A-02-BS2: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-06-0238-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0238-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 405 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 405 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 311 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0238-01A-02D-0310-01): tumor purity 0.78, ploidy 1.99, whole-genome doublings 0.
